Somatic mutation profile of tumor specimen MP2PRT-PAVCFG-TBP1-A (aliquot MP2PRT-PAVCFG-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVCFG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,560 days).
Specimen MP2PRT-PAVCFG-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f19013d7-63bb-4010-89f7-a59fed55d97f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVCFG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVCFG-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc8ddd41-83e2-4ec4-a1fb-62a41df7852d

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, 3'Flank 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 39/319 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CACNA1S | c.1576G>A p.V526M | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs557195329, COSV100754754; called by muse, mutect2, varscan2
- PAPPA | c.3127G>A p.G1043R | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1028529154, COSV60279080; called by muse, mutect2, varscan2
- PLPP7 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 98/442 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1480482439, COSV64836156; called by muse, mutect2, varscan2
- SYCP1 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV65699049; called by muse, varscan2
- CTCF | c.1117C>G p.H373D | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- THAP5 | c.457G>A p.A153T (on ENST00000415914 / NM_001130475.3; = p.A111T on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRDD2 | c.8_9insGGA p.Y3delins* | Nonsense Mutation (INS) | VAF 49/122 reads (40%) | called by mutect2, pindel, varscan2
- ANKRD34C | c.972A>G p.S324= | Silent (SNP) | VAF 74/449 reads (16%) | called by muse, mutect2, varscan2
- FFAR3 | c.726C>T p.N242= | Silent (SNP) | VAF 73/405 reads (18%) | catalogued as rs147416906, COSV59909420; called by muse, mutect2, varscan2
- LRGUK | c.2331C>T p.T777= | Silent (SNP) | VAF 43/230 reads (19%) | catalogued as rs778423903, COSV53637969; called by muse, mutect2, varscan2
- AL031315.1 | c.686-2005C>T | Intron (SNP) | VAF 39/208 reads (19%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins TCTCCGG | 3'Flank (INS) | VAF 12/118 reads (10%) | called by mutect2, pindel
